Somatic mutation profile of tumor specimen TARGET-20-PARERV-09A (aliquot TARGET-20-PARERV-09A-02D) from TARGET case TARGET-20-PARERV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,588 days).
Specimen TARGET-20-PARERV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d7bc191-e77d-41c3-b6bc-10501612e791.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARERV-14A (Bone Marrow Normal), aliquot TARGET-20-PARERV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8e1f693-76ff-428a-9553-12a8112d99ed

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRRAP | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62842499; called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 23/54 reads (43%) | called by mutect2, pindel, varscan2
- ETV6 | c.747dup p.E250Rfs*50 | Frame Shift Ins (INS) | VAF 50/130 reads (38%) | called by mutect2, pindel, varscan2
